Somatic mutation profile of tumor specimen HCM-CSHL-0379-C18-01B (aliquot HCM-CSHL-0379-C18-01B-01D-A79C-36) from HCMI case HCM-CSHL-0379-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,410 days).
Specimen HCM-CSHL-0379-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb6173a6-587e-4c78-a235-0289d95d612a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0379-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0379-C18-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b01d7f7-756c-4f15-a567-f52e590bce19

The open-access MAF lists 68 somatic variants for this specimen: 54 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 12, Nonsense Mutation 5, Intron 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 31/274 reads (11%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 473/601 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RALA | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 37/348 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1554297905, COSV50049211; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs752634323, COSV51072804, COSV51081870; called by muse, mutect2, varscan2
- ANKRD30A | c.1133del p.G378Efs*19 (on ENST00000611781; = p.G322Efs*19 on NM_052997.2) | Frame Shift Del (DEL) | VAF 51/391 reads (13%) | catalogued as COSV64624129; called by mutect2, pindel, varscan2
- APBA2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376193947; called by muse, mutect2, varscan2
- BOC | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as rs1029862359, COSV56355168; called by muse, mutect2, varscan2
- CAPN9 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs370370799; called by muse, mutect2, varscan2
- CCDC87 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs199906600, COSV59578459; called by muse, mutect2, varscan2
- CLCNKB | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777095700; called by muse, mutect2, varscan2
- CREB5 | c.179C>T p.P60L (on ENST00000357727 / NM_182898.4; = p.P53L on NM_004904.3) | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760077074, COSV63220219; called by muse, mutect2, varscan2
- DISP3 | c.592A>G p.N198D | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs769299495; called by muse, mutect2, varscan2
- ELFN2 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as rs372217764; called by muse, mutect2, varscan2
- FBXW10 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759260883; called by muse, varscan2
- GPR173 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100212124; called by muse, mutect2, varscan2
- HECW1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764159115, COSV67835274; called by muse, mutect2, varscan2
- HYDIN | c.7829C>T p.P2610L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs1371650515; called by muse, mutect2, varscan2
- KCNQ3 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267601778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFAP3 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs373189946, COSV100846894; called by muse, mutect2, varscan2
- LAMC1 | c.3595C>T p.R1199* | Nonsense Mutation (SNP) | VAF 60/307 reads (20%) | catalogued as COSV51154755, COSV99280014; called by muse, mutect2, varscan2
- MEGF6 | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs778623137; called by muse, mutect2, varscan2
- MICB | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); catalogued as rs766185724, COSV52855463; called by muse, mutect2, varscan2
- MXRA5 | c.8095C>T p.R2699C | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54252600; called by muse, mutect2, varscan2
- OVOL2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs762166610; called by muse, mutect2, varscan2
- PCDHB3 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.847); catalogued as rs1554272676; called by muse, mutect2, varscan2
- PCDHGA10 | c.2119G>A p.V707I | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as rs369551410; called by muse, varscan2
- PIK3CG | c.2696C>T p.T899M | Missense Mutation (SNP) | VAF 23/436 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs1343056360, COSV63247144; called by muse, mutect2
- PTPRF | c.4234G>T p.D1412Y | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100740851, COSV100741255; called by muse, mutect2
- PTPRS | c.4661C>T p.A1554V | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1191088838, COSV53620761; called by mutect2, varscan2
- PXDNL | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs768124415, COSV62479981, COSV62493818; called by muse, mutect2, varscan2
- RNGTT | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as COSV55647670; called by muse, mutect2, varscan2
- SLITRK5 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); catalogued as COSV100281278, COSV61524178; called by muse, mutect2
- SPATA31A3 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1426644880; called by muse, mutect2, varscan2
- TCFL5 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.566); catalogued as rs780872850, COSV53896319; called by muse, mutect2, varscan2
- TEKT4 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs114824441, COSV54622572; called by muse, mutect2, varscan2
- TEX15 | c.1504G>T p.D502Y (on ENST00000256246; = p.D885Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV56346990; called by muse, mutect2, varscan2
- TMEM200A | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs201700503, COSV51648975, COSV99759901; called by muse, mutect2, varscan2
- TMEM71 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs200344505, COSV100785636, COSV63457874; called by muse, mutect2, varscan2
- TPST1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376840313; called by muse, mutect2, varscan2
- TTN | c.63238G>A p.E21080K (on ENST00000591111; = p.E13656K on NM_003319.4) | Missense Mutation (SNP) | VAF 42/273 reads (15%) | PolyPhen probably damaging (0.994); catalogued as rs374492812; ClinVar: uncertain significance / benign / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2422G>T p.V808F | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- AMER1 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 80/213 reads (38%) | called by muse, mutect2, varscan2
- AREL1 | c.2156C>G p.A719G | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CDCP1 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CDK13 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL6A3 | c.2362C>A p.Q788K | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ICAM4 | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- IGHJ1 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 32/164 reads (20%) | called by muse, mutect2
- MYO16 | c.2423A>G p.E808G | Missense Mutation (SNP) | VAF 89/346 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PPFIA1 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SOCS7 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 359/1601 reads (22%) | called by muse, varscan2
- TTN | c.53257G>T p.D17753Y (on ENST00000591111; = p.D10329Y on NM_003319.4) | Missense Mutation (SNP) | VAF 28/300 reads (9%) | PolyPhen probably damaging (0.961); called by muse, mutect2
- DLGAP2 | c.633G>A p.Q211= | Silent (SNP) | VAF 32/239 reads (13%) | called by muse, mutect2, varscan2
- EFTUD2 | c.750G>A p.R250= | Silent (SNP) | VAF 22/314 reads (7%) | catalogued as rs1443647865, COSV68183883; called by muse, mutect2
- HEPHL1 | c.1221C>T p.N407= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as rs557012995, COSV59892696; called by muse, mutect2, varscan2
- HIVEP3 | c.666C>T p.C222= | Silent (SNP) | VAF 33/176 reads (19%) | catalogued as rs756968051, COSV56009945; called by muse, mutect2, varscan2
- KCNH2 | c.546G>A p.S182= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs773030045; called by muse, mutect2, varscan2
- LITAF | c.354C>T p.S118= | Silent (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- MAGEB6 | c.468G>A p.S156= | Silent (SNP) | VAF 75/236 reads (32%) | catalogued as rs777376582, COSV66871871, COSV66872222; called by muse, mutect2, varscan2
- MUC16 | c.27975C>T p.A9325= | Silent (SNP) | VAF 33/235 reads (14%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1413C>T p.R471= (on ENST00000379409; = p.R419= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as rs937172119; called by muse, mutect2, varscan2
- RFPL2 | c.738C>T p.D246= | Silent (SNP) | VAF 40/241 reads (17%) | catalogued as rs749206718, COSV99964579; called by muse, mutect2, varscan2
- S1PR4 | c.51G>A p.A17= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as rs763097963; called by muse, mutect2, varscan2
- ZNF786 | c.1893C>T p.R631= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as COSV60277551; called by muse, mutect2, varscan2
- CELF1 | c.-125T>A | 5'UTR (SNP) | VAF 36/294 reads (12%) | called by muse, mutect2, varscan2
- LAMA4 | c.297+2342G>A | Intron (SNP) | VAF 43/287 reads (15%) | catalogued as rs367709337; called by muse, mutect2, varscan2
